Somatic mutation profile of tumor specimen TCGA-A4-A772-01A (aliquot TCGA-A4-A772-01A-11D-A33Q-10) from TCGA case TCGA-A4-A772, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 39.1 years (14,278 days).
Specimen TCGA-A4-A772-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acc421b8-ef6c-425c-a7fa-224905ef0141.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-A772-10A (Blood Derived Normal), aliquot TCGA-A4-A772-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e59f8575-708f-4850-9922-978a0cde71ed

The open-access MAF lists 48 somatic variants for this specimen: 34 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 26, Silent 14, Frame Shift Del 4, Nonsense Mutation 2, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.14827A>G p.I4943V | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV101291299; called by muse, mutect2, varscan2
- ACOX2 | c.1885T>G p.F629V | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as rs1312822866, COSV100250117; called by muse, mutect2, varscan2
- ARHGEF11 | c.3333-1G>A p.X1111_splice | Splice Site (SNP) | VAF 23/63 reads (37%) | catalogued as COSV100168500; called by muse, mutect2, varscan2
- CACNA1B | c.4108G>C p.V1370L | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV99496747; called by muse, mutect2, varscan2
- CADM2 | c.1096G>A p.D366N (on ENST00000407528 / NM_001167674.2; = p.D368N on NM_153184.4) | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101052820, COSV101054383; called by muse, mutect2, varscan2
- CEP250 | c.3544C>G p.L1182V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100698876; called by muse, mutect2
- CREB3L1 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs748283344, COSV99914961; called by muse, mutect2, varscan2
- CTSC | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs886048742, COSV99910628; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCT | c.237C>A p.N79K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100986178; called by muse, mutect2
- EFNA5 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as COSV60959941; called by muse, mutect2, varscan2
- HAMP | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | catalogued as COSV99723097; called by muse, mutect2, varscan2
- IPO4 | c.750C>A p.C250* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as COSV99937928; called by muse, mutect2, varscan2
- KCNH7 | c.2254G>A p.G752S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs745497316, COSV100147562; called by muse, mutect2, varscan2
- LRP12 | c.1030G>C p.V344L | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.992); catalogued as rs1327879007, COSV99407541; called by muse, mutect2, varscan2
- MSH4 | c.2695G>A p.A899T | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV99591363; called by muse, mutect2, varscan2
- NDUFB4 | c.382T>A p.S128T | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.047); catalogued as COSV99481809; called by muse, mutect2, varscan2
- NRDC | c.2831A>G p.Y944C | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV100703309; called by muse, mutect2, varscan2
- NXF1 | c.1232A>G p.H411R | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99585968; called by muse, mutect2
- OR10H2 | c.131T>G p.L44R | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100008731; called by muse, mutect2, varscan2
- OXA1L | c.1211T>C p.I404T (on ENST00000285848; = p.I344T on NM_005015.5) | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99591114; called by muse, mutect2, varscan2
- PYCR2 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs150712428; called by muse, mutect2, varscan2
- RAB3GAP1 | c.137A>G p.K46R | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.15); catalogued as COSV99920956; called by muse, mutect2, varscan2
- RING1 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.046); catalogued as rs528777843, COSV63002236; called by muse, mutect2, varscan2
- SLC35F5 | c.126G>C p.K42N | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV99829997; called by muse, mutect2, varscan2
- SLCO4A1 | c.1531C>A p.Q511K | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV99414666; called by muse, mutect2, varscan2
- STXBP3 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 76/241 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100893957; called by muse, mutect2, varscan2
- TBX21 | c.1437G>C p.E479D | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV99455990; called by muse, mutect2, varscan2
- TRIOBP | c.5752G>A p.A1918T (on ENST00000644935 / NM_001039141.3; = p.A205T on NM_007032.5) | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV100462279; called by muse, mutect2, varscan2
- UBC | c.497C>T p.T166I | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100298918; called by muse, mutect2
- FRMD3 | c.156_159del p.K53Gfs*44 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | called by mutect2, pindel, varscan2
- IGHG1 | c.443A>C p.D148A | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- SLC6A6 | c.1746_1765del p.R583Cfs*53 | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | called by mutect2, pindel, varscan2
- SPTBN5 | c.10993del p.R3665Gfs*33 | Frame Shift Del (DEL) | VAF 27/76 reads (36%) | called by mutect2, pindel, varscan2
- TP53BP2 | c.1119del p.K374Sfs*18 (on ENST00000343537 / NM_001031685.3; = p.K245Sfs*18 on NM_005426.2) | Frame Shift Del (DEL) | VAF 25/89 reads (28%) | called by mutect2, pindel, varscan2
- ABCC3 | c.3456G>A p.S1152= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as rs142831476; called by muse, mutect2, varscan2
- KEL | c.51A>C p.A17= | Silent (SNP) | VAF 73/134 reads (54%) | catalogued as COSV100787019; called by muse, mutect2, varscan2
- MYH7B | c.4092G>T p.R1364= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV52683142, COSV99328222; called by muse, mutect2, varscan2
- NT5M | c.294A>T p.S98= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV101198572; called by muse, mutect2, varscan2
- PKP2 | c.1362T>A p.T454= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV99297560; called by muse, mutect2, varscan2
- PKP4 | c.1296T>A p.T432= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV101080721; called by muse, mutect2, varscan2
- PNPLA4 | c.99G>C p.V33= | Silent (SNP) | VAF 26/150 reads (17%) | catalogued as COSV101124375; called by muse, mutect2, varscan2
- QTRT2 | c.684C>T p.T228= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as COSV99846874; called by muse, mutect2, varscan2
- RNF10 | c.171C>T p.S57= | Silent (SNP) | VAF 43/84 reads (51%) | catalogued as rs146802529; called by muse, mutect2, varscan2
- SERPINA5 | c.6G>A p.Q2= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs746075573, COSV61573786; called by muse, varscan2
- SLC44A2 | c.171T>C p.H57= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as rs376552555; called by muse, mutect2, varscan2
- SOHLH1 | c.411G>C p.S137= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100039909, COSV100040106; called by muse, mutect2, varscan2
- TMTC4 | c.1308C>A p.T436= (on ENST00000376234 / NM_001350577.2; = p.T455= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as rs757662415, COSV100168620; called by muse, mutect2, varscan2
- TTN | c.4317T>G p.P1439= (on ENST00000591111; = p.P1393= on NM_003319.4) | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as COSV100606500; called by muse, mutect2
